Somatic mutation profile of tumor specimen TCGA-5M-AATA-01A (aliquot TCGA-5M-AATA-01A-31D-A40P-10) from TCGA case TCGA-5M-AATA, project TCGA-COAD (Colon Adenocarcinoma).
Specimen TCGA-5M-AATA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c443cb78-63e4-40de-9103-36ac9ee95dab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5M-AATA-10A (Blood Derived Normal), aliquot TCGA-5M-AATA-10A-01D-A40P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1060634b-d8be-4e6b-85b7-d10e69200a7c

The open-access MAF lists 84 somatic variants for this specimen: 57 protein-altering or splice-affecting, 27 silent.
By variant classification: Missense Mutation 45, Silent 27, Nonsense Mutation 6, Splice Site 2, In Frame Del 1, Frame Shift Del 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADARB1 | c.1808G>A p.R603Q (on ENST00000360697 / NM_001346687.2; = p.R563Q on NM_001112.4) | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1364071684, COSV62346726; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 46/214 reads (21%) | catalogued as rs1554074738, CM106349, COSV57324862, COSV99966134; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 123/418 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRB3 | c.2875G>A p.V959I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1371872262; called by muse, mutect2, varscan2
- ATP13A1 | c.2060C>T p.A687V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs915249699; called by muse, mutect2, varscan2
- CFAP206 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs965639371, COSV51532520; called by muse, mutect2, varscan2
- DCAF8L1 | c.1662C>G p.H554Q | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV71595347; called by muse, mutect2, varscan2
- DGKZ | c.2277C>T p.A759= (on ENST00000454345 / NM_001105540.2; = p.A571= on NM_003646.4) | Splice Region (SNP) | VAF 15/59 reads (25%) | catalogued as rs1400532378; called by muse, mutect2, varscan2
- DNAJC3 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | catalogued as COSV65130872; called by muse, mutect2, varscan2
- DOCK6 | c.2771G>A p.R924H | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747986259; called by muse, mutect2, varscan2
- GALNT9 | c.1327C>A p.R443S (on ENST00000328957 / NM_001122636.2; = p.R77S on NM_021808.3) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV61096889; called by muse, mutect2, varscan2
- GLRA3 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | catalogued as rs201620617; called by muse, mutect2, varscan2
- GRHL2 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs774477960; called by muse, mutect2, varscan2
- KCNG1 | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV65367911; called by muse, mutect2, varscan2
- KRT31 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs148992540; called by muse, mutect2, varscan2
- MARVELD2 | c.1578del p.E527Nfs*6 | Frame Shift Del (DEL) | VAF 154/486 reads (32%) | catalogued as COSV57780447; called by mutect2, varscan2
- MEIOC | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs145444080; called by muse, varscan2
- MEX3B | c.1525G>A p.G509R | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.731); catalogued as rs775399651; called by muse, mutect2, varscan2
- NCOA2 | c.2690C>A p.T897N | Missense Mutation (SNP) | VAF 47/336 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV51219712; called by muse, mutect2, varscan2
- NUP153 | c.3106G>A p.A1036T | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs374947018, COSV50461432; called by muse, mutect2, varscan2
- NYAP2 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 116/340 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs774734033, COSV56004596; called by muse, mutect2, varscan2
- OR2T6 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as rs199789023, COSV63216786; called by muse, mutect2, varscan2
- RBM10 | c.433-2A>T p.X145_splice | Splice Site (SNP) | VAF 20/33 reads (61%) | catalogued as COSV61310191; called by muse, mutect2, varscan2
- RDX | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as rs764536750, COSV100562675; called by muse, mutect2, varscan2
- TCF7L2 | c.1258C>T p.R420W (on ENST00000355995 / NM_001367943.1; = p.R397W on NM_030756.5) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53335898; called by muse, mutect2, varscan2
- TEPSIN | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs758539478, COSV56144165; called by muse, mutect2, varscan2
- TKTL2 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as rs115895686; called by muse, mutect2, varscan2
- TNFRSF11B | c.997C>G p.R333G | Missense Mutation (SNP) | VAF 47/264 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52070601; called by muse, mutect2, varscan2
- TTLL12 | c.521A>G p.N174S | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.119); catalogued as rs1489819341, COSV99333895; called by muse, mutect2, varscan2
- YTHDF3 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.412); catalogued as rs373841599; called by muse, mutect2, varscan2
- ZBTB47 | c.1603G>A p.V535M | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779717013; called by muse, mutect2, varscan2
- ZNF536 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1223055764, COSV62831990, COSV62835027; called by muse, mutect2, varscan2
- ZNF586 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as rs746337591; called by muse, mutect2, varscan2
- ZSCAN20 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 39/148 reads (26%) | catalogued as rs999656787; called by muse, mutect2, varscan2
- ARHGEF11 | c.3125C>T p.A1042V | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ATP9A | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTFR | c.749T>C p.I250T | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DEUP1 | c.427_428dup p.L143Ffs*2 | Frame Shift Ins (INS) | VAF 35/192 reads (18%) | called by mutect2, pindel, varscan2
- DPT | c.432-2A>C p.X144_splice | Splice Site (SNP) | VAF 24/71 reads (34%) | called by muse, mutect2, varscan2
- GPR6 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.906); called by muse, mutect2
- HSPB6 | c.311A>C p.E104A | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- IL16 | c.3211G>A p.D1071N (on ENST00000302987 / NM_172217.5; = p.D370N on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KMT2B | c.3274T>C p.S1092P | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MARS1 | c.2108A>G p.D703G | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MCM10 | c.2046G>T p.K682N (on ENST00000484800 / NM_182751.3; = p.K681N on NM_018518.5) | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- NCAPG | c.2476G>T p.V826L | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- NRCAM | c.1504T>C p.Y502H (on ENST00000379028 / NM_001371124.1; = p.Y496H on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OR13J1 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM19 | c.1889T>A p.L630Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.3); called by muse, mutect2
- SCN7A | c.2368A>T p.I790F | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- SIPA1L3 | c.3352C>A p.P1118T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC4A9 | c.1633G>A p.G545S (on ENST00000507527 / NM_001258428.2; = p.G521S on NM_031467.3) | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- SREK1IP1 | c.346_354del p.E116_K118del | In Frame Del (DEL) | VAF 61/196 reads (31%) | called by mutect2, pindel, varscan2
- TANC2 | c.2080A>T p.K694* | Nonsense Mutation (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- TRPM7 | c.510G>T p.W170C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBQLN2 | c.172A>C p.K58Q | Missense Mutation (SNP) | VAF 169/273 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ZFPM2 | c.3379C>T p.Q1127* | Nonsense Mutation (SNP) | VAF 39/293 reads (13%) | called by muse, mutect2, varscan2
- ACSM2A | c.1728G>T p.A576= (on ENST00000219054; = p.A497= on NM_001308169.2) | Silent (SNP) | VAF 38/134 reads (28%) | called by muse, mutect2, varscan2
- ACTN2 | c.1422C>T p.H474= | Silent (SNP) | VAF 87/215 reads (40%) | catalogued as rs1282303942, COSV63974636; called by muse, mutect2, varscan2
- AMDHD1 | c.1224C>T p.G408= | Silent (SNP) | VAF 99/376 reads (26%) | catalogued as COSV54118152; called by muse, mutect2, varscan2
- ARHGEF17 | c.4071C>T p.D1357= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as rs144162252; called by muse, mutect2, varscan2
- CACNA1B | c.3891C>T p.A1297= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs758677283, COSV53137175; called by muse, mutect2, varscan2
- CDH15 | c.1665C>T p.H555= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs879802247; called by muse, mutect2
- CDON | c.2922C>T p.G974= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as rs771769883, COSV54995602; called by muse, mutect2, varscan2
- COL11A1 | c.1098C>T p.D366= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs369719875, COSV62197766; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL5A1 | c.4782C>T p.D1594= | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as rs372971566; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBN3 | c.1692G>A p.A564= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs746969140, COSV54460354; called by muse, mutect2, varscan2
- ITGAX | c.3285G>C p.T1095= | Silent (SNP) | VAF 12/135 reads (9%) | catalogued as COSV99192070; called by muse, mutect2
- LOXL2 | c.1488C>T p.H496= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs374553547; called by muse, mutect2, varscan2
- MMP16 | c.414C>T p.N138= | Silent (SNP) | VAF 131/191 reads (69%) | catalogued as rs758117384, COSV54184654, COSV99688157; called by muse, mutect2, varscan2
- NLGN4X | c.1137C>T p.F379= | Silent (SNP) | VAF 106/203 reads (52%) | catalogued as rs1453809585, COSV99322174; called by muse, mutect2, varscan2
- NOG | c.189G>A p.E63= | Silent (SNP) | VAF 59/231 reads (26%) | called by muse, mutect2, varscan2
- NUTM2F | c.1140G>A p.R380= | Silent (SNP) | VAF 17/132 reads (13%) | called by muse, mutect2, varscan2
- PCDHB9 | c.2097G>A p.S699= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV53375074; called by muse, mutect2, varscan2
- PDHX | c.111A>G p.V37= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV53507768; called by muse, mutect2
- PHLDB3 | c.294G>A p.A98= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV52668750; called by muse, mutect2, varscan2
- PIGR | c.1305C>T p.D435= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs771103207; called by muse, mutect2, varscan2
- SHANK1 | c.6150C>T p.F2050= | Silent (SNP) | VAF 61/151 reads (40%) | catalogued as rs768023321, COSV53245282; called by muse, mutect2, varscan2
- SMO | c.1338C>T p.N446= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs536563919, COSV99976365; called by muse, mutect2, varscan2
- TMOD3 | c.513A>G p.E171= | Silent (SNP) | VAF 52/149 reads (35%) | catalogued as rs1401861568; called by muse, mutect2, varscan2
- VARS1 | c.2283G>A p.A761= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs1431262169, COSV63305127; called by muse, mutect2, varscan2
- ZFP3 | c.753A>G p.K251= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs1428052469; called by muse, mutect2, varscan2
- ZFR2 | c.2055G>A p.T685= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as rs367706746; called by muse, mutect2, varscan2
- ZNF549 | c.1659C>T p.G553= (on ENST00000376233 / NM_001199295.2; = p.G540= on NM_153263.2) | Silent (SNP) | VAF 50/159 reads (31%) | catalogued as rs748754204; called by muse, mutect2, varscan2
